Somatic mutation profile of tumor specimen 0DZ2GH from CCDI case PBCTNR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 0.1 years (54 days).
Specimen 0DZ2GH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f7f4f70-f571-4a55-98bc-f93b548e5013.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZ2G7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97b98ff2-7660-43a2-bda6-6b9980470ca8

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLG2 | c.1457C>T p.S486L | Missense Mutation (SNP) | VAF 22/731 reads (3%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as COSV66174458; called by muse, mutect2
- C16orf96 | c.3265C>A p.P1089T | Missense Mutation (SNP) | VAF 54/633 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2
- SP140 | c.1120C>A p.P374T | Missense Mutation (SNP) | VAF 38/498 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); called by muse, mutect2
